Gene-level copy-number profile of tumor specimen TCGA-AG-3999-01A from TCGA case TCGA-AG-3999, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 61.1 years (22,311 days).
Specimen TCGA-AG-3999-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.c486199f-b2be-48a7-b4ee-274dfa2ca9c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3999-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b3f4815-d2f2-40ed-8c07-99717d582424

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 1,120; copy number 2: 17,716; copy number 3: 26,058; copy number 4: 9,982; copy number 5: 505; copy number 6: 2,456; copy number 7: 1,516; copy number 8: 122; copy number 9: 124; copy number 10: 7; copy number 11: 4; copy number 12: 90; copy number 13: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3999-01A-01D-1428-01): tumor purity 0.72, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–4,994,972, 64 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,856 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–121,580,524, 78 genes, copy number 7 (broad region; genes not listed).
- chr1:147,019,656–147,993,592, 30 genes, copy number 8–9: AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B.
- chr1:160,876,540–163,076,802, 90 genes, copy number 8–12 (broad region; genes not listed).
- chr5:45,254,948–45,895,970, 4 genes, copy number 11 (within-gene range 2–11): HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr12:24,642,687–26,421,462, 44 genes, copy number 13: AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1.
- chr12:26,335,864–26,373,733, 2 genes, copy number 13: AC055720.2, RNA5SP354.
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 7 (broad region; genes not listed).
- chr20:32,052,197–35,412,031, 115 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:55,997,357–59,469,853, 95 genes, copy number 9 (broad region; genes not listed).
- chr20:59,933,764–60,653,784, 7 genes, copy number 10 (within-gene range 2–10): FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646.

Autosomal genes at a single copy (total copy number 1): 1,120. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
